Somatic mutation profile of tumor specimen C3L-01040-02 (aliquot CPT0171580011) from CPTAC case C3L-01040, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 77.7 years (28,387 days).
Specimen C3L-01040-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96964d01-6b96-4d6b-b366-b0c1843f8cee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01040-31 (Blood Derived Normal), aliquot CPT0171540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/261956d1-193d-4f1b-87a6-cf3682c595d1

The open-access MAF lists 119 somatic variants for this specimen: 81 protein-altering or splice-affecting, 28 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 28, Nonsense Mutation 6, Frame Shift Del 5, Intron 5, RNA 2, Splice Site 2, In Frame Del 2, 3'UTR 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs749795819; called by muse, mutect2
- ADGRG2 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 63/100 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as rs753491583, COSV61341782; called by muse, mutect2, varscan2
- ADGRG4 | c.287A>C p.H96P | Missense Mutation (SNP) | VAF 119/191 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs758323226; called by muse, mutect2, varscan2
- BATF | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 63/484 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54376709; called by muse, mutect2, varscan2
- CCDC183 | c.1600_1602del p.K534del | In Frame Del (DEL) | VAF 88/293 reads (30%) | catalogued as rs759937715; called by pindel, varscan2
- CEACAM7 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782499272, COSV50073488; called by muse, mutect2, varscan2
- COL10A1 | c.1696G>A p.G566R | Missense Mutation (SNP) | VAF 157/583 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as rs759704485; called by muse, mutect2, varscan2
- DNASE1 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 78/476 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as rs747491349; called by muse, mutect2, varscan2
- ENPEP | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs546059710, COSV54454005, COSV54454423; called by muse, mutect2, varscan2
- FAM50B | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 91/239 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1436984887, COSV66654807; called by muse, mutect2, varscan2
- FANCL | c.471G>A p.K157= | Splice Region (SNP) | VAF 93/372 reads (25%) | catalogued as COSV52072973; called by muse, mutect2, varscan2
- FBLN2 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs375179920; called by muse, mutect2, varscan2
- FYB1 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 159/479 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs373802950; called by muse, mutect2, varscan2
- GALNTL6 | c.84del p.W28Cfs*10 | Frame Shift Del (DEL) | VAF 176/582 reads (30%) | catalogued as COSV72553121; called by mutect2, pindel, varscan2
- H2BW1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 166/528 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs782006019; called by muse, mutect2, varscan2
- HCN3 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369007284, COSV61362426; called by muse, mutect2, varscan2
- HECW1 | c.3230G>A p.G1077E | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs267601513; called by muse, mutect2, varscan2
- KIF19 | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV63430641; called by muse, mutect2, varscan2
- KLHL9 | c.668T>A p.L223Q | Missense Mutation (SNP) | VAF 188/623 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62921431; called by muse, mutect2, varscan2
- KPNA5 | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1306351165; called by muse, mutect2, varscan2
- L3MBTL2 | c.1101G>A p.W367* | Nonsense Mutation (SNP) | VAF 94/196 reads (48%) | catalogued as rs1393086112; called by muse, mutect2, varscan2
- LGALS16 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 117/472 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as rs747258971; called by muse, mutect2, varscan2
- METTL3 | c.1518+1G>T p.X506_splice | Splice Site (SNP) | VAF 178/504 reads (35%) | catalogued as COSV52969092; called by muse, mutect2, varscan2
- MGAM | c.4159C>T p.R1387C | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs753437264, COSV72073746; called by muse, mutect2
- MRGPRX3 | c.707G>A p.W236* | Nonsense Mutation (SNP) | VAF 52/422 reads (12%) | catalogued as rs774168391, COSV101283574; called by muse, mutect2, varscan2
- MXRA5 | c.7636G>A p.D2546N | Missense Mutation (SNP) | VAF 106/201 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs778756027; called by muse, mutect2, varscan2
- NRCAM | c.640G>A p.E214K (on ENST00000379028 / NM_001371124.1; = p.E208K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/320 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as rs752888953, COSV61030980; called by muse, mutect2, varscan2
- OR2A14 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 289/1019 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1196303037; called by muse, mutect2, varscan2
- OR2G6 | c.947A>G p.D316G | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100598125; called by muse, mutect2
- OR51S1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 103/332 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs560546339, COSV59057342; called by muse, mutect2
- OR6V1 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 66/477 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as rs750436531, COSV69237145; called by muse, mutect2, varscan2
- PABPC1L | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 118/589 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV53842212; called by muse, mutect2, varscan2
- PPFIA2 | c.3477G>C p.Q1159H | Missense Mutation (SNP) | VAF 112/369 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV61030004; called by muse, mutect2, varscan2
- PRKG2 | c.1934C>T p.T645M | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs575558482; called by muse, mutect2
- QSOX2 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs770075933, COSV62393409; called by muse, mutect2, varscan2
- RNF17 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs746275549, COSV55042705, COSV55050126; called by muse, mutect2, varscan2
- SLITRK6 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.643); catalogued as COSV68390482; called by muse, mutect2
- TNK2 | c.2864C>T p.A955V | Missense Mutation (SNP) | VAF 105/354 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs772461175; called by muse, mutect2, varscan2
- UGT2B15 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 28/280 reads (10%) | catalogued as rs138640811; called by muse, mutect2, varscan2
- VWDE | c.3991G>A p.D1331N | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs1562466560, COSV51727033; called by muse, mutect2, varscan2
- ZNF638 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.162); catalogued as COSV52484967; called by muse, mutect2, varscan2
- ADAM9 | c.334-1G>A p.X112_splice | Splice Site (SNP) | VAF 30/245 reads (12%) | called by muse, mutect2, varscan2
- CASZ1 | c.2237A>G p.Q746R | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- DNER | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DSC1 | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 79/290 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZR1 | c.1478C>T p.T493I (on ENST00000395095 / NM_001136198.1; = p.T490I on NM_016263.4) | Missense Mutation (SNP) | VAF 132/636 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GLI1 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 16/311 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPM6B | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 63/89 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- GREB1L | c.904A>T p.N302Y | Missense Mutation (SNP) | VAF 103/364 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ITPR3 | c.6665T>A p.F2222Y | Missense Mutation (SNP) | VAF 120/517 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITPR3 | c.6667T>C p.Y2223H | Missense Mutation (SNP) | VAF 118/506 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LIPE | c.3047_3067del p.L1016_L1022del | In Frame Del (DEL) | VAF 69/401 reads (17%) | called by mutect2, pindel
- LRRC4C | c.1831G>C p.V611L | Missense Mutation (SNP) | VAF 68/497 reads (14%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTV1 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 197/667 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- LY86 | c.178A>T p.K60* | Nonsense Mutation (SNP) | VAF 49/185 reads (26%) | called by muse, mutect2, varscan2
- LZTR1 | c.495G>A p.W165* | Nonsense Mutation (SNP) | VAF 100/187 reads (53%) | called by muse, mutect2, varscan2
- MUC16 | c.13916C>T p.P4639L | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC5B | c.7947del p.S2650Pfs*13 | Frame Shift Del (DEL) | VAF 266/1511 reads (18%) | called by mutect2, pindel, varscan2
- MYO1D | c.491A>T p.K164I | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NIPAL1 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 112/374 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NUDT7 | c.262A>T p.T88S | Missense Mutation (SNP) | VAF 91/340 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- P2RY8 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 61/365 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PARP12 | c.1888G>A p.G630S | Missense Mutation (SNP) | VAF 145/742 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCBP2 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 124/460 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCLO | c.3349G>A p.G1117R | Missense Mutation (SNP) | VAF 62/255 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PER1 | c.1076T>G p.I359S | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- POGLUT2 | c.883G>A p.G295S | Missense Mutation (SNP) | VAF 162/465 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R16B | c.1471A>T p.K491* | Nonsense Mutation (SNP) | VAF 115/477 reads (24%) | called by muse, mutect2, varscan2
- REM1 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SALL4 | c.959C>T p.T320I | Missense Mutation (SNP) | VAF 17/521 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0.444); called by muse, mutect2
- SCRT2 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- SIGLEC7 | c.176A>T p.D59V | Missense Mutation (SNP) | VAF 208/980 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLITRK6 | c.233T>A p.M78K | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- THOC1 | c.145del p.C49Vfs*11 | Frame Shift Del (DEL) | VAF 60/181 reads (33%) | called by mutect2, pindel, varscan2
- TIMM22 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TMEM169 | c.481G>T p.V161F | Missense Mutation (SNP) | VAF 197/624 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- USF1 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2
- USP33 | c.378_385del p.K126Nfs*23 | Frame Shift Del (DEL) | VAF 31/162 reads (19%) | called by mutect2, pindel, varscan2
- VWDE | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 37/391 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.045); called by muse, mutect2
- XPC | c.2185G>C p.D729H | Missense Mutation (SNP) | VAF 93/317 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF729 | c.2582_2583del p.F861* | Frame Shift Del (DEL) | VAF 67/429 reads (16%) | called by mutect2, pindel, varscan2
- ABCC3 | c.2988A>G p.T996= | Silent (SNP) | VAF 245/943 reads (26%) | called by muse, mutect2, varscan2
- AHNAK2 | c.9873G>A p.E3291= | Silent (SNP) | VAF 247/880 reads (28%) | catalogued as COSV60933175; called by muse, mutect2, varscan2
- ATP8A2 | c.2463C>T p.D821= | Silent (SNP) | VAF 90/312 reads (29%) | catalogued as rs759374071, COSV54947644; called by mutect2, varscan2
- CAPN5 | c.684C>T p.D228= (on ENST00000456580; = p.D188= on NM_004055.5) | Silent (SNP) | VAF 72/503 reads (14%) | catalogued as rs781820376; called by muse, mutect2, varscan2
- CDH17 | c.414C>T p.N138= | Silent (SNP) | VAF 36/268 reads (13%) | called by muse, mutect2, varscan2
- DCHS2 | c.1554G>T p.P518= | Silent (SNP) | VAF 25/192 reads (13%) | catalogued as COSV100252175; called by muse, mutect2, varscan2
- FOXI3 | c.1173C>T p.S391= | Silent (SNP) | VAF 172/547 reads (31%) | catalogued as rs774808218, COSV101230929, COSV67916871; called by muse, mutect2, varscan2
- GLRA1 | c.324C>T p.D108= | Silent (SNP) | VAF 294/876 reads (34%) | catalogued as rs762489154, COSV51008327; ClinVar: benign; called by muse, mutect2, varscan2
- IGHA1 | c.807G>A p.Q269= | Silent (SNP) | VAF 142/1315 reads (11%) | called by muse, mutect2, varscan2
- LILRB5 | c.439C>T p.L147= | Silent (SNP) | VAF 68/302 reads (23%) | catalogued as rs781019591; called by muse, mutect2, varscan2
- LRRC32 | c.1578G>A p.L526= | Silent (SNP) | VAF 161/405 reads (40%) | catalogued as rs760410034; called by muse, mutect2, varscan2
- MAML1 | c.2613G>A p.Q871= | Silent (SNP) | VAF 253/805 reads (31%) | called by muse, mutect2, varscan2
- MUC17 | c.13065C>T p.L4355= | Silent (SNP) | VAF 29/266 reads (11%) | catalogued as rs375383681; called by muse, mutect2, varscan2
- MYO15A | c.10005C>T p.S3335= | Silent (SNP) | VAF 194/690 reads (28%) | catalogued as rs751601405, COSV99233828; called by muse, mutect2, varscan2
- MYOM2 | c.2964C>T p.D988= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as rs139273975, COSV50701992; called by muse, mutect2, varscan2
- NFKBIZ | c.231C>T p.S77= | Silent (SNP) | VAF 23/178 reads (13%) | catalogued as rs753478094; called by muse, mutect2, varscan2
- OR8D2 | c.270C>T p.N90= | Silent (SNP) | VAF 80/221 reads (36%) | catalogued as rs778035575; called by muse, mutect2, varscan2
- PCDH11Y | c.207C>T p.N69= (on ENST00000400457 / NM_032973.2; = p.N58= on NM_032971.3) | Silent (SNP) | VAF 272/393 reads (69%) | catalogued as COSV53093000; called by muse, mutect2, varscan2
- PDZD2 | c.2895C>T p.Y965= | Silent (SNP) | VAF 220/662 reads (33%) | catalogued as rs371895164; called by muse, mutect2, varscan2
- PHLPP1 | c.1173G>A p.P391= | Silent (SNP) | VAF 42/286 reads (15%) | catalogued as rs1368148443; called by muse, mutect2, varscan2
- RNF207 | c.1260C>T p.F420= | Silent (SNP) | VAF 44/179 reads (25%) | catalogued as rs369466699; called by muse, mutect2, varscan2
- RNF32 | c.355C>T p.L119= | Silent (SNP) | VAF 78/398 reads (20%) | catalogued as rs541447710; called by muse, mutect2, varscan2
- SLC9A3 | c.363C>T p.P121= | Silent (SNP) | VAF 33/242 reads (14%) | catalogued as rs769744437; called by muse, mutect2, varscan2
- SORL1 | c.2430C>T p.D810= | Silent (SNP) | VAF 85/244 reads (35%) | catalogued as rs370375010; called by muse, mutect2, varscan2
- TRRAP | c.10689C>T p.T3563= (on ENST00000359863 / NM_001244580.1; = p.T3534= on NM_003496.3) | Silent (SNP) | VAF 148/583 reads (25%) | called by muse, mutect2, varscan2
- TTC31 | c.792C>T p.G264= | Silent (SNP) | VAF 122/360 reads (34%) | called by muse, mutect2, varscan2
- ZKSCAN7 | c.1029T>C p.D343= | Silent (SNP) | VAF 64/207 reads (31%) | called by muse, mutect2, varscan2
- ZNF324 | c.177C>T p.P59= | Silent (SNP) | VAF 100/625 reads (16%) | called by muse, mutect2, varscan2
- C2CD5 | c.2534-2376C>G | Intron (SNP) | VAF 68/190 reads (36%) | catalogued as rs1480287395; called by muse, mutect2, varscan2
- FOXA1 | c.72+770G>A | Intron (SNP) | VAF 58/202 reads (29%) | catalogued as rs1411771766; called by muse, mutect2, varscan2
- IGFL2 | c.*27C>T | 3'UTR (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- MILR1 | chr17:64468350 G>A | 3'Flank (SNP) | VAF 82/237 reads (35%) | catalogued as rs1402394412; called by muse, mutect2, varscan2
- MVB12A | c.*6C>T | 3'UTR (SNP) | VAF 57/199 reads (29%) | called by muse, mutect2, varscan2
- OR2A13P | n.796C>T | RNA (SNP) | VAF 64/600 reads (11%) | catalogued as rs771707940; called by muse, varscan2
- PCCA | c.1900-23791_1900-23789del | Intron (DEL) | VAF 80/319 reads (25%) | called by pindel, varscan2
- SERPINB13 | c.473-316G>T | Intron (SNP) | VAF 36/269 reads (13%) | called by muse, mutect2, varscan2
- SSPOP | n.1185C>T | RNA (SNP) | VAF 46/516 reads (9%) | catalogued as rs569866191, COSV50487238; called by muse, mutect2
- TFCP2 | c.123-6156G>A | Intron (SNP) | VAF 213/680 reads (31%) | catalogued as rs1273113276; called by muse, mutect2, varscan2
